Gene-level copy-number profile of tumor specimen MP2PRT-PAVPAF-TMP1-A from MP2PRT case MP2PRT-PAVPAF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.9 years (5,807 days).
Specimen MP2PRT-PAVPAF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 884d0bb0-4b21-4c58-b637-346a6ecfbcf0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVPAF-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/fb861efa-d914-4f51-bd02-adb443403ea9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 36; copy number 3: 105; copy number 4: 41,037; copy number 5: 129; copy number 6: 14,583; copy number 7: 88; copy number 8: 2,346; copy number 9: 5; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–4): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–3): TRDD1, TRDD2, TRDD3, TRDJ1.
- chr14:105,881,034–106,005,574, 35 genes (within-gene range 0–4): IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:14,061–86,265, 4 genes, copy number 9: AC215217.1, AL713922.1, TUBB8, IL9RP2.
- chr17:142,789–181,650, 1 gene, copy number 10: DOC2B.

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
